Gene-level copy-number profile of tumor specimen TCGA-VQ-A8DT-01A from TCGA case TCGA-VQ-A8DT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 43.6 years (15,937 days).
Specimen TCGA-VQ-A8DT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.0dd97d2f-66fd-4056-ae5c-d1d5c0280c5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8DT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fe6ae535-4549-4b40-bc1a-dfba0288949f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,429; copy number 2: 9,382; copy number 3: 42,378; copy number 4: 4,810; copy number 5: 285; copy number 6: 358; copy number 7: 9; copy number 8: 131; copy number 10: 8; copy number 13: 8; copy number 15: 1; copy number 17: 1; copy number 18: 12; copy number 19: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8DT-01A-11D-A363-01): tumor purity 0.9, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 176 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:96,377,857–98,401,090, 39 genes, copy number 8 (within-gene range 6–8): RNU7-188P, SEM1, MARK2P10, RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1, RN7SKP104, TAC1, ASNS, AC079781.5, AC005326.1, SNRPCP9, RPS3AP29, AC079781.1, AC079781.2, AC079781.4, AC079781.3, OR7E7P, MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1, OCM2, RN7SL478P, LMTK2, BHLHA15, TECPR1, BRI3, BAIAP2L1, AC093799.1.
- chr7:103,074,881–107,717,809, 77 genes, copy number 8 (broad region; genes not listed).
- chr7:110,108,031–110,534,757, 1 gene, copy number 8 (within-gene range 3–8): AC073114.1.
- chr7:110,590,082–111,562,517, 3 genes, copy number 8 (within-gene range 3–14): AC073326.2, IMMP2L, AC073326.1.
- chr8:1,763,888–1,958,627, 1 gene, copy number 15 (within-gene range 4–17): AC019257.8.
- chr8:1,823,926–1,958,641, 1 gene, copy number 17 (within-gene range 4–17): ARHGEF10.
- chr8:10,606,349–10,839,847, 7 genes, copy number 7–8 (within-gene range 5–8): RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1.
- chr8:10,825,373–11,201,833, 8 genes, copy number 7 (within-gene range 4–7): MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5.
- chr8:11,247,626–11,869,533, 25 genes, copy number 8–18 (within-gene range 4–18): LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB.
- chr8:28,600,469–29,263,124, 14 genes, copy number 10–19 (within-gene range 4–19): EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2, KIF13B, AC108449.3, AC108449.1, HMGB1P23.

Autosomal genes at a single copy (total copy number 1): 39. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
